Gene-level copy-number profile of tumor specimen SM-JU32N from CPTAC case C224106, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Parietal lobe; Tumor grade: G4.
Specimen SM-JU32N: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file eda02e67-d250-4cb4-8aae-5d3d4740c1d9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105215 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/4b4c64c3-7172-45fc-8331-a458ba34b31b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 7,732; copy number 2: 46,139; copy number 3: 4,864; copy number 4: 81; copy number 29: 2; copy number 30: 2.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,058,771–25,938,434, 74 genes (broad region; genes not listed).
- chr14:18,333,726–18,343,144, 2 genes: CR383658.1, RNU6-458P.
- chr22:18,361,820–18,719,341, 19 genes: FAM230J, AC011718.1, PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:42,794,906–42,844,438, 2 genes, copy number 30: TCP1P1, AC010132.1.
- chr7:53,655,508–53,811,952, 1 gene, copy number 29 (within-gene range 2–29): LINC01446.
- chr7:54,933,699–54,938,184, 1 gene, copy number 29: AC006971.1.

Autosomal genes at a single copy (total copy number 1): 4,876. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
